Gene-level copy-number profile of specimen HCM-STAN-0841-C18-85A from HCMI case HCM-STAN-0841-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G1; Age at diagnosis: 62.2 years (22,736 days).
Specimen HCM-STAN-0841-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3224f9a8-699d-41cc-b6bf-34f71cb7ea9b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-0841-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,256 have no estimate.
https://portal.gdc.cancer.gov/files/74ec6016-93e8-4114-ab32-88e90ec5a06a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 18; copy number 2: 9,358; copy number 3: 13,999; copy number 4: 26,682; copy number 5: 498; copy number 6: 6,198; copy number 7: 1,609; copy number 9: 2; copy number 10: 1; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:22,178,107–22,185,402, 2 genes, copy number 9: IGHV1OR15-3, IGHV4OR15-8.
- chr20:19,756,390–19,823,943, 2 genes, copy number 14: AL121761.1, RPL12P12.
- chr21:8,603,547–8,603,984, 1 gene, copy number 10: RPSAP68.

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
